CCDI case PBCBFK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/c1fe8e12-4170-4607-a7d3-7b1fef9aa79f

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 14.7 years (5,375 days).

Biospecimens (2 samples)
- Sample 0DNCH2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNCOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
